Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A83F, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A83F-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME: SURG PATH #:
MR #: SPECIMEN CLASS:
BILLING #: ALT ID #:
LOCATION: DATE OF PROCEDURE:
AGE: DATE RECEIVED:
SEX: M TIME RECEIVED:
DOB: DATE OF REPORT:
PHYSICIAN: DATE OF PRINTING:
COPY TO:

Material Received:

A: right obturator lymph node
B: left obturator lymph node
C: prostate

History:

year old male with a clinical history of prostate cancer.

Final Diagnosis:

- A. Lymph node (6), "right obturator lymph node", excision:
There is no evidence of malignancy in 6 lymph nodes (0/6).
- B. Lymph node (2), "left obturator lymph node", excision:
There is no evidence of malignancy in 2 lymph nodes (0/2).
- C. Prostate, "prostate", prostatectomy
Prostatic adenocarcinoma, Gleason score = 3 + 4 (7/10), with extraprostatic extension. See comment.

Comment:

PROSTATE CANCER CHECKLIST:

Procedure: Prostatectomy

Histologic Type: Adenocarcinoma

Histologic Grade: Moderately differentiated

Gleason Pattern

Primary Pattern: 3

Secondary Pattern: 4

Total Gleason Score: 7

Proportion (percentage) of prostatic tissue involved by tumor: 40%

Extraprostatic Extension: Present, established (non-focal)

Seminal Vesicle Invasion: Not identified

Margins: Focally present at the right posterior margin

Treatment Effect on Carcinoma: Not applicable

Lymph-Vascular Invasion: Not identified

Lymph Nodes:

Number Examined: 7

Number Involved: 0

ICD 0-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 861.9
7/11/13

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Perineural Invasion: Present

Additional Pathologic Findings: Focal high grade prostatic intraepithelial neoplasia

Pathologic Staging (pTNM): pT3a N0

Primary Tumor (pT)

pT3a: Extraprostatic extension or microscopic invasion of bladder neck

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at this case has been concurrently reviewed by the following pathologist: who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Interpreted by:
Electronically Signed Out By
MD, Attending Physician
M.D., Resident

Gross Description:

A. Received in formalin labeled with the patient's name and "right obturator lymph node" is a 3.5 x 3.0 x 0.5 cm aggregate of pale tan-yellow irregular soft tissue fragments. The specimen is palpated to reveal six possible lymph nodes which measure from 0.4 x 0.2 x 0.2 cm up to 2.0 x 0.7 x 0.3 cm.

- A1 Two possible lymph nodes.
- A2 Two possible lymph nodes.
- A3 Two possible lymph nodes.

B. Received in formalin labeled with the patient's name and "left obturator lymph node" is a 2.5 x 2.0 x 1.0 cm aggregate of pale tan-yellow grossly fatty tissue fragments. The specimen is palpated to reveal two possible lymph nodes which measure 1.0 x 0.5 x 0.3 cm and 1.5 x 0.8 x 0.3 cm.

- B1 Two possible lymph nodes.

C. Received fresh labeled with the patient's name and "prostate" is a 52 gram prostate measuring 5.8 cm from right to left, 4.3 cm from anterior to posterior, and 4.9 cm from superior to inferior. The right seminal vesicle appears to be detached but the remaining portion measures 1.0 x 0.8 x 0.3 cm, the right vas deferens measures 3.8 cm in length and 0.5 cm in diameter, the left vas deferens measures 3.9 cm in length and 0.5 cm in diameter and the left seminal vesicle measures 2.6 x 1.0 x 0.5 cm. The external surface of the prostate is smooth and tan-pink. The right side of the prostate is inked black and the left side is inked orange. The prostate is serially sectioned to reveal a 0.8 x 0.7 x 0.5 cm white-tan mass in the left anterior lobe. This mass is 0.4 cm from the closest margin. The remainder of the cut-surface is yellow-tan and nodular. The specimen is submitted as follows:

- C1 Right bladder neck margin.
- C2 Left bladder neck margin.
- C3 Right distal urethral margin.
- C4 Left distal urethral margins.
- C5 Right and left seminal vesicle and vas deferens margins. C6
Representative section from the right mid-anterior prostate.
- C7 Representative section from the left mid-anterior prostate.
- C8-C18 Entire posterior right lobe, from apex to base (cassettes C16-C17 are one section, bisected)
- C19-C31 Entire posterior left lobe, from apex to base.

M.D., Resident

Date of Printing:

MR #:

Page 2 of 3

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Date of Printing:

MR #:

Page 3 of 3

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file bcd6d454-d0b5-4cf8-a49e-e9c796a2321a (TCGA-XJ-A83F.FAFE6F58-BE44-442F-B0E6-F3D7BD60EFBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).